Surgical pathology report (de-identified scan), TCGA case TCGA-AG-4008, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-4008-01A (Primary Tumor).

[REDACTED]

In I) this is an invasive, poorly differentiated adenocarcinoma of the colon (G3) with penetration of all the parietal layers and vascular infiltrates (pT3, L1, V1).

Tumor classification:

ICDO-DA-M

8140/3

G3

pT3

L1, V1,

pN0

MX

consistent with R0

[REDACTED]

Source: NCI Genomic Data Commons file cd376fcc-69bc-42d4-b91f-fc3fcbe8e8a9 (TCGA-AG-4008.44DA5CC5-93F9-4D13-846F-46DDCDDA016C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).